Gene-level copy-number profile of tumor specimen C3L-00581-01 from CPTAC case C3L-00581, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,213 days).
Specimen C3L-00581-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file acc40677-492b-4082-ab57-656f9cb3cf1a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00581-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/806e2c3b-5f16-4eda-a2f3-c5482895cae6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 8,765; copy number 2: 47,667; copy number 3: 2,428.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
